Somatic mutation profile of tumor specimen 0DDHT5 from CCDI case PBBMRT, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Neoplasm, malignant; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 7.6 years (2,781 days).
Specimen 0DDHT5: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3835ad0b-dbe2-42dc-815f-1604030f7a0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DDHT6 (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/0e5d5731-b442-475a-9751-67932f0f4d5c

The open-access MAF lists 8 somatic variants for this specimen: 5 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ALPK2 | c.5093C>T p.S1698L | Missense Mutation (SNP) | VAF 131/249 reads (53%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs375605840, COSV64490108; called by muse, mutect2, varscan2
- MEX3A | c.266C>T p.P89L | Missense Mutation (SNP) | VAF 38/75 reads (51%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.018); catalogued as rs971101234; called by muse, mutect2, varscan2
- CIC | c.1453G>C p.D485H | Missense Mutation (SNP) | VAF 203/496 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KLHL13 | c.589del p.V197Lfs*12 | Frame Shift Del (DEL) | VAF 186/440 reads (42%) | called by mutect2, varscan2
- WAS | c.1316G>A p.R439Q | Missense Mutation (SNP) | VAF 267/624 reads (43%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.978); called by muse, mutect2, varscan2
- CLSTN3 | c.2436C>T p.H812= | Silent (SNP) | VAF 62/433 reads (14%) | catalogued as rs754758010, COSV104384421; called by muse, mutect2, varscan2
- TADA2B | c.93G>T p.L31= | Silent (SNP) | VAF 9/76 reads (12%) | called by muse, mutect2
- LILRB2 | c.35-78G>A | Intron (SNP) | VAF 31/73 reads (42%) | called by muse, mutect2, varscan2
